Somatic mutation profile of tumor specimen C3N-02976-01 (aliquot CPT0188030006) from CPTAC case C3N-02976, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.6 years (25,797 days).
Specimen C3N-02976-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a75fe1d4-3412-4d57-8b01-92c1d490d677.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02976-31 (Blood Derived Normal), aliquot CPT0188090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ccb0a8b-7814-458a-ace9-18242b243248

The open-access MAF lists 1,280 somatic variants for this specimen: 897 protein-altering or splice-affecting, 214 silent, 169 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 571, Silent 214, Frame Shift Del 205, Intron 82, Frame Shift Ins 42, Nonsense Mutation 38, 3'UTR 35, 5'UTR 20, Splice Region 15, RNA 15, In Frame Del 15, 5'Flank 12.

Variants (750 of 1,280; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 126/286 reads (44%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CDKL5 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 114/256 reads (45%) | catalogued as rs587783159, COSV66111263, COSV66111271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 150/324 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, varscan2
- IQSEC2 | c.4419del p.S1474Vfs*21 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs1569290954; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 41/505 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1381851622, COSV66464105; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- KMT2B | c.4204C>T p.R1402* | Nonsense Mutation (SNP) | VAF 90/206 reads (44%) | catalogued as rs1555730957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.9417del p.K3140Rfs*2 | Frame Shift Del (DEL) | VAF 74/220 reads (34%) | catalogued as rs1555190550; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, varscan2
- MPV17 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 240/576 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121909723, CM061856, COSV51992038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3263del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 148/428 reads (35%) | hotspot (GDC flag); catalogued as COSV52278003; called by mutect2, pindel, varscan2
- MYO7A | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 59/202 reads (29%) | catalogued as rs376764423, CM138861; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 144/328 reads (44%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PRPS1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 154/352 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs137852544, CM952243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.114del p.L39Cfs*41 | Frame Shift Del (DEL) | VAF 125/318 reads (39%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 354/401 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.2849dup p.L950Ffs*4 | Frame Shift Ins (INS) | VAF 146/384 reads (38%) | catalogued as rs1470463921; ClinVar: pathogenic; called by mutect2, varscan2
- AATK | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 158/351 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs750474216; called by muse, mutect2, varscan2
- ABHD17A | c.461C>T p.S154L (on ENST00000292577 / NM_001130111.2; = p.S205L on NM_031213.4) | Missense Mutation (SNP) | VAF 273/623 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs777774406, COSV51751609; called by muse, mutect2, varscan2
- ABHD3 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs992864031, COSV56678839; called by muse, mutect2, varscan2
- ACACA | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as rs1475270333; called by muse, mutect2, varscan2
- ACP5 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 236/545 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs113122216; called by muse, mutect2, varscan2
- ACTB | c.363+5G>A | Splice Region (SNP) | VAF 135/343 reads (39%) | catalogued as rs754820594; called by muse, mutect2, varscan2
- ADCY7 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs763347673; called by muse, mutect2, varscan2
- ADGRA2 | c.3257del p.P1086Lfs*217 | Frame Shift Del (DEL) | VAF 62/210 reads (30%) | catalogued as rs1189742043; called by mutect2, pindel, varscan2
- ADRB2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs1209605702, COSV60005301; called by muse, mutect2, varscan2
- AFG1L | c.358dup p.S120Ffs*59 | Frame Shift Ins (INS) | VAF 29/91 reads (32%) | catalogued as rs764712525; called by mutect2, pindel, varscan2
- AHCY | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 176/384 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.318); catalogued as rs563484762, CM1513675, COSV54152966; called by muse, mutect2, varscan2
- AHDC1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766945203; called by muse, mutect2, varscan2
- AHNAK | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as rs757522801, COSV99945148; called by muse, mutect2, varscan2
- ALDH1L1 | c.295del p.R99Gfs*62 | Frame Shift Del (DEL) | VAF 71/181 reads (39%) | catalogued as rs755422577, COSV99856805; called by mutect2, pindel, varscan2
- ALG10 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201276321, COSV56791855; called by muse, mutect2, varscan2
- ALOX12 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs1321896069; called by muse, mutect2
- AMOTL2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 189/423 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs765734570, COSV51439072; called by muse, mutect2, varscan2
- AMY1A | c.1037A>G p.H346R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1339556066; called by mutect2, varscan2
- ANGPTL1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as rs1008176981, COSV52367362; called by muse, mutect2, varscan2
- ANK3 | c.13045T>C p.S4349P (on ENST00000280772 / NM_001320874.2; = p.S973P on NM_001149.3) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as rs138857513; called by muse, mutect2, varscan2
- ANKRD11 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 174/437 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs758856347, COSV56375421; called by muse, mutect2, varscan2
- ANKRD24 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs376946018, COSV99517486; called by muse, mutect2, varscan2
- ANKRD49 | c.617del p.N206Tfs*52 | Frame Shift Del (DEL) | VAF 134/419 reads (32%) | catalogued as rs774975121; called by mutect2, pindel, varscan2
- ANKRD52 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 143/302 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1383780431; called by muse, varscan2
- ANKRD52 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 159/395 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs914481646, COSV57281912; called by muse, varscan2
- ANO2 | c.364G>A p.V122I (on ENST00000356134 / NM_001278597.3; = p.V126I on NM_001278596.3) | Missense Mutation (SNP) | VAF 270/553 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1299653264, COSV59006843; called by muse, mutect2, varscan2
- ANO5 | c.108_109del p.E36Dfs*7 | Frame Shift Del (DEL) | VAF 119/431 reads (28%) | catalogued as rs886044020; called by pindel, varscan2
- ANXA10 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 92/224 reads (41%) | catalogued as COSV63738005; called by muse, mutect2
- APC2 | c.6764dup p.F2256Lfs*52 | Frame Shift Ins (INS) | VAF 133/324 reads (41%) | catalogued as rs776761485; called by mutect2, pindel, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 149/366 reads (41%) | catalogued as rs773922861; called by mutect2, pindel, varscan2
- ARHGEF1 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 186/432 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs1555849325, COSV100529055; called by muse, varscan2
- ARHGEF18 | c.3331G>A p.A1111T (on ENST00000359920 / NM_001130955.2; = p.A1007T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs779578688; called by muse, mutect2, varscan2
- ARHGEF4 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 149/339 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs778882777; called by muse, mutect2, varscan2
- ARHGEF40 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.022); catalogued as rs761654072, COSV100069956; called by muse, mutect2, varscan2
- ARID1B | c.1243del p.A415Pfs*15 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs1417035592; called by mutect2, pindel, varscan2
- ARID4A | c.1568dup p.N523Kfs*11 | Frame Shift Ins (INS) | VAF 79/231 reads (34%) | catalogued as rs1215325775; called by mutect2, pindel, varscan2
- ARMC5 | c.170dup p.I58Nfs*45 | Frame Shift Ins (INS) | VAF 82/227 reads (36%) | catalogued as rs951869246; called by mutect2, pindel, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 58/188 reads (31%) | catalogued as rs753865255; called by mutect2, varscan2
- ARVCF | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1439091104; called by muse, mutect2, varscan2
- ASAP3 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1260013457, COSV60873426; called by muse, mutect2, varscan2
- ASCC2 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs769624519, COSV100316172, COSV100316331; called by muse, mutect2, varscan2
- ASCL2 | c.461del p.G154Afs*23 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs1233059351; called by mutect2, pindel, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 205/495 reads (41%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPM | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 293/641 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99659924; called by muse, mutect2, varscan2
- ASPSCR1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.148); catalogued as rs200437145, COSV100144672; called by muse, mutect2, varscan2
- ATAD2B | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 80/179 reads (45%) | catalogued as COSV99478746; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | catalogued as rs768611141; called by mutect2, pindel
- ATP9B | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777654085; called by muse, mutect2, varscan2
- ATXN1 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV104392032; called by muse, mutect2, varscan2
- ATXN1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as rs770179993; called by muse, mutect2, varscan2
- B4GALT6 | c.868T>C p.W290R | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52702442; called by muse, mutect2, varscan2
- B4GALT7 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as COSV50352592; called by muse, mutect2, varscan2
- BAG6 | c.2965del p.Q989Sfs*85 (on ENST00000676571; = p.Q942Sfs*85 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/170 reads (42%) | catalogued as rs778695310; called by mutect2, varscan2
- BCL11B | c.2269G>A p.G757R (on ENST00000357195 / NM_001282237.2; = p.G686R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 294/624 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV104421084; called by muse, mutect2, varscan2
- BCLAF1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs148908235; called by muse, mutect2, varscan2
- BECN1 | c.1068del p.L357Cfs*77 | Frame Shift Del (DEL) | VAF 64/166 reads (39%) | catalogued as rs1395644174; called by mutect2, pindel, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 40/89 reads (45%) | catalogued as rs749168305; called by mutect2, varscan2
- BEND5 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 234/564 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1415597483, COSV65718585; called by muse, mutect2, varscan2
- BOC | c.2269A>G p.S757G | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1225054171; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 88/220 reads (40%) | catalogued as rs752512017; called by mutect2, varscan2
- C16orf96 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs367941862; called by muse, mutect2, varscan2
- C2orf81 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.784); catalogued as COSV99292385; called by muse, mutect2, varscan2
- C5orf38 | c.226del p.D76Mfs*5 | Frame Shift Del (DEL) | VAF 72/202 reads (36%) | catalogued as rs746245907, COSV57410849; called by mutect2, pindel, varscan2
- CA1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs769195145; called by muse, mutect2, varscan2
- CACNB1 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs769993738; called by muse, mutect2, varscan2
- CACNB3 | c.472+13del | Splice Region (DEL) | VAF 52/141 reads (37%) | catalogued as rs778256532; called by mutect2, pindel, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CALHM4 | c.794G>T p.R265L (on ENST00000368596 / NM_001366078.1; = p.R79L on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs202028712, COSV63985364; called by muse, mutect2, varscan2
- CARMIL3 | c.4015del p.L1339* | Frame Shift Del (DEL) | VAF 157/388 reads (40%) | catalogued as rs1167529280; called by mutect2, pindel, varscan2
- CASP7 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764815610, COSV61880865; called by muse, mutect2, varscan2
- CBX2 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1179841115, COSV53969489; called by muse, mutect2, varscan2
- CCDC149 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775699302; called by muse, mutect2, varscan2
- CCDC158 | c.3064C>T p.H1022Y | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs367625662; called by muse, mutect2, varscan2
- CCDC40 | c.2235+1del | Frame Shift Del (DEL) | VAF 159/430 reads (37%) | catalogued as COSV66475310; called by mutect2, pindel, varscan2
- CCDC65 | c.793dup p.I265Nfs*21 | Frame Shift Ins (INS) | VAF 106/235 reads (45%) | catalogued as rs751586867; called by mutect2, varscan2
- CCDC97 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs1357572445; called by muse, mutect2, varscan2
- CCM2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 300/670 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs371371873; called by muse, mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | catalogued as rs781790231; called by mutect2, varscan2
- CD19 | c.1646del p.G549Afs*31 (on ENST00000324662 / NM_001178098.2; = p.G548Afs*31 on NM_001770.6) | Frame Shift Del (DEL) | VAF 103/316 reads (33%) | catalogued as rs1157860951; called by mutect2, pindel, varscan2
- CDK3 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361788666; called by muse, mutect2, varscan2
- CEBPA | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs974386262; called by muse, mutect2, varscan2
- CELSR2 | c.4144G>A p.G1382S | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs375870109; called by muse, mutect2, varscan2
- CFAP54 | c.6121C>T p.R2041C | Missense Mutation (SNP) | VAF 142/370 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs757234138; called by muse, mutect2, varscan2
- CHMP3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs368950086; called by muse, mutect2, varscan2
- CIC | c.4487G>A p.R1496H | Missense Mutation (SNP) | VAF 249/590 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200799936; ClinVar: not provided; called by muse, mutect2, varscan2
- CLDN20 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs978739766; called by muse, mutect2, varscan2
- CLDN6 | c.567dup p.S190Vfs*24 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | catalogued as rs756736939; called by mutect2, varscan2
- CNKSR1 | c.2009G>T p.G670V (on ENST00000374253 / NM_001297647.2; = p.G663V on NM_006314.3) | Missense Mutation (SNP) | VAF 168/412 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV58793744; called by muse, mutect2, varscan2
- COL6A5 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs1288968128; called by muse, mutect2, varscan2
- COPS5 | c.921-5del | Splice Region (DEL) | VAF 26/58 reads (45%) | catalogued as rs200155628; called by mutect2, varscan2
- COQ9 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 360/846 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs748239782, COSV52646559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPQ | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs577356141, COSV55138391; called by muse, mutect2, varscan2
- CR2 | c.624dup p.T209Hfs*3 | Frame Shift Ins (INS) | VAF 244/653 reads (37%) | catalogued as rs747832403; called by mutect2, varscan2
- CRACD | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1333990857; called by muse, mutect2
- CSNK1A1L | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs748596649, COSV65789483, COSV65790082; called by muse, mutect2, varscan2
- CT47B1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 304/687 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1171676848, COSV64890367, COSV64890418; called by muse, mutect2, varscan2
- CTBP2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs758782963, COSV58336407; called by muse, mutect2, varscan2
- CTDSPL2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as COSV52946960; called by muse, varscan2
- CYP2F1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV58528858; called by muse, mutect2
- CYP4F2 | c.986-3del | Splice Region (DEL) | VAF 11/105 reads (10%) | catalogued as rs1271723179; called by mutect2, pindel, varscan2
- DHX33 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 205/482 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1261578076; called by muse, mutect2, varscan2
- DLX6 | c.270C>G p.H90Q | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.082); catalogued as rs1462940513; called by muse, mutect2, varscan2
- DMXL2 | c.8408A>G p.Q2803R | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99196151; called by muse, mutect2, varscan2
- DNAH17 | c.6455C>T p.P2152L | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs751432691; called by muse, mutect2, varscan2
- DNAH17 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as rs868532432, COSV67750733; called by muse, mutect2, varscan2
- DNAH7 | c.2275del p.I759Sfs*5 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as COSV56778434; called by mutect2, pindel
- DNAH8 | c.5138G>A p.R1713H | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs758923038, COSV59423705; called by muse, mutect2, varscan2
- DNAH9 | c.5660T>C p.L1887P | Missense Mutation (SNP) | VAF 117/291 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778001850; called by muse, mutect2, varscan2
- DNAJB12 | c.772C>T p.R258C (on ENST00000338820; = p.R224C on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 178/446 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1179618570; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 52/128 reads (41%) | catalogued as rs750262341; called by mutect2, varscan2
- DVL2 | c.1801del p.A601Qfs*80 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | catalogued as rs745455027; called by mutect2, pindel, varscan2
- DYNC2I2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs1405671782; called by muse, mutect2, varscan2
- DYNC2I2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147957478; called by muse, mutect2, varscan2
- DYRK1B | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as rs771887480; called by muse, mutect2, varscan2
- E4F1 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 220/493 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs892168093, COSV57038173; called by muse, mutect2, varscan2
- EGF | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 136/319 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs201626324, COSV54483787; called by muse, varscan2
- EGFLAM | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | catalogued as rs1220128597, COSV59295089; called by muse, mutect2, varscan2
- EID2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 184/355 reads (52%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.597); catalogued as rs768798913; called by muse, mutect2, varscan2
- EIF4EBP1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs765723849; called by muse, mutect2, varscan2
- EME2 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs374046300; called by muse, mutect2, varscan2
- ENPP1 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 148/424 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs546032693; called by muse, mutect2, varscan2
- EPHA2 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 200/430 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.645); catalogued as rs1380907401; called by muse, mutect2, varscan2
- EVA1B | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 276/583 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1268513604; called by muse, mutect2, varscan2
- EXOC6B | c.916-1G>A p.X306_splice | Splice Site (SNP) | VAF 96/293 reads (33%) | catalogued as COSV99067078; called by muse, mutect2, varscan2
- EXPH5 | c.5489T>C p.L1830P | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.843); catalogued as rs1236102749; called by muse, mutect2, varscan2
- FABP3 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as rs556881362; called by muse, mutect2, varscan2
- FAM120AOS | c.683del p.K228Rfs*22 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV52905526; called by mutect2, pindel, varscan2
- FAM187A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 165/391 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs773383135; called by muse, mutect2, varscan2
- FAM47B | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs775436289, COSV100264090, COSV61453106; called by muse, mutect2, varscan2
- FAM71E2 | c.1913del p.G638Afs*24 | Frame Shift Del (DEL) | VAF 66/205 reads (32%) | catalogued as COSV58483611; called by mutect2, pindel, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 91/202 reads (45%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT1 | c.11856del p.F3952Lfs*31 | Frame Shift Del (DEL) | VAF 141/377 reads (37%) | catalogued as rs1166479124; called by mutect2, pindel, varscan2
- FAT3 | c.12127+1del | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as COSV53164453, COSV53177295; called by mutect2, pindel, varscan2
- FBN1 | c.5798A>G p.E1933G | Missense Mutation (SNP) | VAF 183/434 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as CM096459; called by muse, mutect2, varscan2
- FBRSL1 | c.876del p.A293Pfs*121 | Frame Shift Del (DEL) | VAF 72/197 reads (37%) | catalogued as rs1461432773; called by mutect2, pindel, varscan2
- FBXO11 | c.363C>T p.G121= (on ENST00000403359 / NM_001190274.2; = p.G37= on NM_025133.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 51/178 reads (29%) | catalogued as rs756494130, COSV57025236; called by muse, mutect2, varscan2
- FBXO41 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs765916084; called by muse, mutect2, varscan2
- FCAR | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs143972917; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 40/92 reads (43%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FGFR4 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52804167; called by muse, mutect2, varscan2
- FOCAD | c.2791del p.S931Afs*11 | Frame Shift Del (DEL) | VAF 80/210 reads (38%) | catalogued as rs776730128; called by mutect2, pindel, varscan2
- FOXD4L3 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 252/584 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs782113259, COSV100730992; called by muse, mutect2, varscan2
- FOXE1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 126/287 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as COSV100909947; called by muse, mutect2, varscan2
- FOXP3 | c.191T>C p.M64T | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV66051726; called by muse, mutect2, varscan2
- FOXP4 | c.895G>A p.G299S (on ENST00000307972 / NM_001012426.1; = p.G298S on NM_138457.3) | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200034711; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2010G>A p.R670= | Splice Region (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100437606; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 86/226 reads (38%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FUBP1 | c.1345-5del | Splice Region (DEL) | VAF 71/178 reads (40%) | catalogued as rs545766306; called by mutect2, varscan2
- FURIN | c.1383del p.I461Mfs*11 | Frame Shift Del (DEL) | VAF 41/131 reads (31%) | catalogued as COSV51576145; called by mutect2, pindel, varscan2
- FXYD5 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs770139102; called by muse, mutect2, varscan2
- G6PD | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 184/396 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1359222355; called by mutect2, varscan2
- GBA3 | c.912dup p.A305Cfs*29 | Frame Shift Ins (INS) | VAF 52/127 reads (41%) | catalogued as rs776182136; called by mutect2, varscan2
- GEMIN8 | c.280A>G p.R94G | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs767611226; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 100/247 reads (40%) | catalogued as rs771881138; called by mutect2, varscan2
- GLCCI1 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56200863; called by muse, mutect2, varscan2
- GPR137 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057129800, COSV57402308; called by muse, mutect2, varscan2
- GRM3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV64467252; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 48/94 reads (51%) | catalogued as rs754199513; called by mutect2, varscan2
- GZF1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 138/271 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs968445902, COSV57634829; called by muse, mutect2, varscan2
- HAO1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs148371109; called by muse, varscan2
- HAUS4 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs771325556; called by muse, mutect2, varscan2
- HCN1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 184/452 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs375110542; called by mutect2, varscan2
- HIC2 | c.1842del p.S615Pfs*25 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | catalogued as COSV101335588; called by mutect2, pindel, varscan2
- HIVEP3 | c.5320C>T p.R1774C | Missense Mutation (SNP) | VAF 253/603 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781723244, COSV56014915; called by muse, mutect2, varscan2
- HJURP | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 144/308 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs914831404; called by muse, mutect2, varscan2
- HMCN1 | c.14510G>A p.R4837Q | Missense Mutation (SNP) | VAF 165/361 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs752242653, COSV54888710; called by muse, mutect2, varscan2
- HMCN2 | c.14575G>A p.G4859R | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781592159; called by muse, mutect2, varscan2
- IGFBP4 | c.123del p.V42Wfs*52 | Frame Shift Del (DEL) | VAF 142/346 reads (41%) | catalogued as rs778799414; called by mutect2, varscan2
- IL17RA | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 250/559 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752747061; called by muse, mutect2, varscan2
- IL4I1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 263/598 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs768142263; called by muse, mutect2, varscan2
- ILDR2 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 148/330 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV54829409; called by muse, mutect2, varscan2
- IMP4 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 135/317 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1279962306; called by muse, mutect2, varscan2
- INPPL1 | c.2012_2013del p.Y671Cfs*19 | Frame Shift Del (DEL) | VAF 44/143 reads (31%) | catalogued as rs1226924888; called by pindel, varscan2
- INTS1 | c.5189C>T p.P1730L | Missense Mutation (SNP) | VAF 142/317 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs758106722; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 61/163 reads (37%) | catalogued as rs1561359523; called by mutect2, varscan2
- IRX2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 213/556 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57413548; called by muse, mutect2, varscan2
- ISYNA1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 196/473 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs775486515; called by muse, mutect2, varscan2
- ITGAD | c.1273del p.R425Afs*50 | Frame Shift Del (DEL) | VAF 75/253 reads (30%) | catalogued as rs746237579, COSV66756833; called by mutect2, pindel, varscan2
- ITGB2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs147318988, CM014361; called by muse, mutect2, varscan2
- ITPR2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101190291; called by muse, mutect2, varscan2
- JARID2 | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs755051913, COSV59190111; called by muse, mutect2, varscan2
- JHY | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 190/402 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs376060402, COSV57072578; called by muse, mutect2, varscan2
- KANK2 | c.2093A>G p.N698S (on ENST00000586659 / NM_001379562.1; = p.N706S on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100763380; called by muse, mutect2, varscan2
- KAZN | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs748830726; called by muse, mutect2, varscan2
- KBTBD11 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 126/352 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459030148; called by muse, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 93/284 reads (33%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNG2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 138/337 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.063); catalogued as rs766009096; called by muse, mutect2, varscan2
- KCNK2 | c.1232C>T p.T411M (on ENST00000444842 / NM_001017425.3; = p.T396M on NM_014217.4) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs538085965; called by muse, mutect2, varscan2
- KCNT1 | c.805G>T p.G269C (on ENST00000488444; = p.G288C on NM_020822.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as CM1310284, COSV99706005; called by muse, mutect2, varscan2
- KDM7A | c.1206A>G p.I402M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1226214791; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIAA1217 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267602445; called by muse, mutect2, varscan2
- KIAA1522 | c.172del p.H58Tfs*24 (on ENST00000373480 / NM_001198972.2; = p.H117Tfs*24 on NM_020888.3) | Frame Shift Del (DEL) | VAF 79/242 reads (33%) | catalogued as rs767600627; called by mutect2, pindel, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF21A | c.3703del p.I1235Ffs*7 (on ENST00000361418 / NM_001378440.1; = p.I1222Ffs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/202 reads (41%) | catalogued as rs761074592; called by mutect2, varscan2
- KIF27 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 166/353 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs77150451; called by muse, mutect2, varscan2
- KIF5C | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs372092875; called by muse, mutect2, varscan2
- KLKB1 | c.418del p.R140Gfs*29 | Frame Shift Del (DEL) | VAF 144/390 reads (37%) | catalogued as rs755680952; called by mutect2, varscan2
- KMT2B | c.5114G>A p.R1705Q | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555731980, COSV55862448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2E | c.691del p.S231Afs*73 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | catalogued as rs1207852808; called by mutect2, pindel, varscan2
- KMT2E | c.1473dup p.G492Rfs*23 | Frame Shift Ins (INS) | VAF 138/381 reads (36%) | catalogued as rs1259171545; called by mutect2, pindel, varscan2
- KRT17 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 201/478 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs368091501, COSV60860308; called by muse, mutect2, varscan2
- KRT2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); catalogued as rs530180060, COSV59008994; called by muse, mutect2, varscan2
- LATS1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 93/197 reads (47%) | catalogued as COSV53601739; called by muse, mutect2, varscan2
- LDB3 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760563152, COSV53951399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LHFPL4 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867351413, COSV55002368; called by muse, mutect2, varscan2
- LMBR1L | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV57268612; called by muse, mutect2, varscan2
- LONP2 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53526012; called by muse, mutect2, varscan2
- LONRF1 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV68036831; called by muse, mutect2, varscan2
- LRP2 | c.6283C>T p.R2095* | Nonsense Mutation (SNP) | VAF 126/318 reads (40%) | catalogued as rs753549113, COSV55544116; called by muse, varscan2
- LRRC24 | c.251_253del p.N84del | In Frame Del (DEL) | VAF 70/206 reads (34%) | catalogued as rs948236459; called by pindel, varscan2
- LRRC66 | c.2551G>A p.V851I | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773799470; called by muse, mutect2, varscan2
- LRSAM1 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 299/741 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.62); catalogued as COSV55940887; called by muse, mutect2, varscan2
- LRSAM1 | c.2120C>T p.P707L | Missense Mutation (SNP) | VAF 273/630 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797044913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSM11 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs558600570; called by muse, mutect2, varscan2
- LSMEM2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 147/347 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782665715; called by muse, mutect2, varscan2
- LUZP1 | c.1484G>A p.G495D | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as rs1409434891, COSV56505150; called by muse, mutect2
- LUZP4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs936115318, COSV64218417; called by muse, mutect2, varscan2
- LVRN | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 172/397 reads (43%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.838); catalogued as COSV63496963; called by muse, mutect2, varscan2
- LZTS2 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs900315360, COSV99058736; called by muse, mutect2, varscan2
- MAB21L2 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750430131, COSV58260916; called by muse, mutect2, varscan2
- MACF1 | c.11522G>A p.G3841D (on ENST00000372915; = p.G1774D on NM_012090.5) | Missense Mutation (SNP) | VAF 119/292 reads (41%) | catalogued as rs1267303754; called by muse, mutect2, varscan2
- MAGI1 | c.2364del p.K788Nfs*67 (on ENST00000402939 / NM_001033057.2; = p.K788Nfs*28 on NM_004742.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 122/309 reads (39%) | catalogued as COSV100439280; called by mutect2, pindel, varscan2
- MAPK7 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55189997; called by muse, mutect2, varscan2
- MAPK8IP3 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377251085; called by muse, mutect2, varscan2
- MARK3 | c.483+1G>A p.X161_splice | Splice Site (SNP) | VAF 33/83 reads (40%) | catalogued as rs1398990486; called by muse, mutect2, varscan2
- MAST4 | c.4075G>A p.G1359S (on ENST00000403625 / NM_001164664.2; = p.G1170S on NM_015183.3) | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.175); catalogued as rs746603303; called by muse, mutect2, varscan2
- MCM2 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 62/166 reads (37%) | catalogued as rs1457321529; called by muse, mutect2, varscan2
- MCM4 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 145/415 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100031758; called by muse, mutect2, varscan2
- MEFV | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs144998416; called by muse, mutect2, varscan2
- MEGF6 | c.2954G>A p.R985H | Missense Mutation (SNP) | VAF 118/273 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs535529108, COSV53891599; called by muse, mutect2, varscan2
- METAP1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1175207010; called by muse, mutect2, varscan2
- MEX3A | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 210/488 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1316672579, COSV101348977; called by muse, mutect2, varscan2
- MICALL1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 134/311 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs554579323; called by muse, mutect2, varscan2
- MICALL2 | c.2273G>A p.G758D | Missense Mutation (SNP) | VAF 156/356 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52514338; called by muse, mutect2, varscan2
- MIGA1 | c.1188+10dup | Splice Region (INS) | VAF 18/58 reads (31%) | catalogued as rs764028419; called by mutect2, varscan2
- MINAR1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 161/375 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779063853, COSV100548988, COSV59584250; called by muse, mutect2, varscan2
- MPHOSPH10 | c.711del p.F237Lfs*28 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs1179926988; called by mutect2, pindel
- MPND | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779175383; called by muse, mutect2, varscan2
- MRAP2 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV57634176; called by muse, mutect2, varscan2
- MRPS22 | c.350C>T p.A117V (on ENST00000310776 / NM_001363893.1; = p.A118V on NM_020191.4) | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs573115352; called by muse, mutect2, varscan2
- MRPS7 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs370949988; called by muse, mutect2, varscan2
- MTMR11 | c.1909C>T p.R637C (on ENST00000439741 / NM_001145862.2; = p.R565C on NM_181873.3) | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs371578546; called by muse, mutect2
- MUC16 | c.40702T>C p.Y13568H | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66694486; called by muse, mutect2, varscan2
- MYH7B | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 121/302 reads (40%) | catalogued as rs370367964; called by muse, mutect2, varscan2
- MYO3B | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 242/559 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760427310, COSV58699107; called by muse, mutect2, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 97/315 reads (31%) | catalogued as COSV58513333; called by mutect2, pindel, varscan2
- MYRFL | c.2597C>A p.P866H | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV54913813; called by muse, varscan2
- NAPSA | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.503); catalogued as rs760724883; called by muse, mutect2, varscan2
- NAT1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.815); catalogued as rs200857632; called by muse, mutect2, varscan2
- NCAPH | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as rs767913740, COSV53639773; called by muse, mutect2, varscan2
- NCOR1 | c.2570A>G p.D857G | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1470052748; called by muse, mutect2, varscan2
- NDUFA7 | c.197del p.P66Lfs*22 | Frame Shift Del (DEL) | VAF 62/198 reads (31%) | catalogued as rs1426048589; called by mutect2, pindel, varscan2
- NECTIN1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs747681440, COSV50599474; called by muse, varscan2
- NFE2L3 | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 125/294 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs757303428; called by muse, mutect2, varscan2
- NKPD1 | c.1773_1775del p.D591del | In Frame Del (DEL) | VAF 52/138 reads (38%) | catalogued as rs1265429856; called by pindel, varscan2
- NLRP2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 196/508 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); catalogued as rs1473452983, COSV54751859, COSV54752546; called by muse, varscan2
- NLRX1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1475733289; called by muse, mutect2, varscan2
- NOS1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57616898; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 135/358 reads (38%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOX1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.102); catalogued as COSV54193262; called by muse, mutect2, varscan2
- NR1H2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761997652; called by muse, mutect2, varscan2
- NRAP | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs746067972; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 191/447 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs537993529, COSV55933480; called by muse, mutect2, varscan2
- NRXN2 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.024); catalogued as rs373166886, COSV55461558; called by muse, mutect2, varscan2
- NTNG2 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 202/549 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1342385306; called by muse, mutect2, varscan2
- NUTM2G | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 133/636 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs761396273; called by muse, mutect2, varscan2
- OBSCN | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 227/480 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs1284747016, COSV52744540; called by muse, mutect2, varscan2
- OBSL1 | c.458del p.G153Afs*105 | Frame Shift Del (DEL) | VAF 124/309 reads (40%) | catalogued as CX132462; called by mutect2, varscan2
- OCA2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 295/726 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1426141034; called by muse, mutect2, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 60/122 reads (49%) | catalogued as rs777887578; called by mutect2, varscan2
- OIT3 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs776812775; called by muse, mutect2, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 60/175 reads (34%) | catalogued as COSV57137289; called by mutect2, pindel, varscan2
- OR4K2 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as rs1044297225, COSV53848142; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 151/742 reads (20%) | catalogued as rs1566497842; called by mutect2, pindel, varscan2
- OR5D18 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs768748128, COSV100450684, COSV61736976; called by muse, mutect2, varscan2
- OR5H1 | c.921dup p.H308Tfs*3 | Frame Shift Ins (INS) | VAF 52/125 reads (42%) | catalogued as rs750155763; called by mutect2, varscan2
- OR5R1 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100393630; called by muse, mutect2, varscan2
- OSBPL2 | c.1380del p.D461Tfs*44 (on ENST00000313733 / NM_144498.4; = p.D449Tfs*44 on NM_014835.4) | Frame Shift Del (DEL) | VAF 131/375 reads (35%) | catalogued as rs1298433831; called by mutect2, pindel, varscan2
- OSGEP | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1305108351, COSV52834321; called by muse, mutect2, varscan2
- OTOF | c.3269C>T p.A1090V (on ENST00000272371 / NM_194248.3; = p.A343V on NM_004802.4) | Missense Mutation (SNP) | VAF 196/454 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs370609551, CM091230; called by muse, mutect2, varscan2
- OTOG | c.6181G>A p.V2061I | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1438322234; called by muse, mutect2, varscan2
- OVOL2 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53861007; called by muse, mutect2, varscan2
- PACS1 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 226/570 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1425006132; called by muse, mutect2, varscan2
- PADI3 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 140/292 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as rs778365044, COSV64934044; called by muse, mutect2, varscan2
- PAFAH1B3 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 119/288 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs557243754; called by muse, mutect2, varscan2
- PAPSS1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 141/273 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1451976968; called by muse, mutect2, varscan2
- PARP14 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.2); catalogued as rs775188052; called by muse, mutect2, varscan2
- PARP2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 111/222 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); catalogued as rs199837737; called by muse, mutect2, varscan2
- PARVG | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs374139833; called by muse, mutect2, varscan2
- PAX1 | c.501del p.S168Afs*47 | Frame Shift Del (DEL) | VAF 165/478 reads (35%) | catalogued as COSV68273123; called by mutect2, pindel, varscan2
- PAX1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 228/549 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1320609661, COSV68272077; called by muse, mutect2, varscan2
- PCDHA10 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 372/858 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs1554150112, COSV56505571; called by muse, mutect2, varscan2
- PCDHA11 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 113/243 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as rs1554165105, COSV56532546; called by muse, mutect2, varscan2
- PCDHB3 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs1554272288; called by muse, mutect2, varscan2
- PCDHB7 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as rs868986357, COSV50755744; called by muse, mutect2, varscan2
- PCDHGA8 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as COSV53943457; called by muse, mutect2, varscan2
- PCLO | c.5564_5566del p.S1855del | In Frame Del (DEL) | VAF 31/75 reads (41%) | catalogued as rs763002987; called by pindel, varscan2
- PDZD2 | c.308del p.G103Afs*19 | Frame Shift Del (DEL) | VAF 185/502 reads (37%) | catalogued as rs750970663; called by mutect2, pindel, varscan2
- PGGHG | c.2020G>T p.G674* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV101164452; called by muse, mutect2, varscan2
- PGM3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756062467; called by muse, mutect2, varscan2
- PGRMC2 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 177/394 reads (45%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs746067498; called by muse, mutect2, varscan2
- PHGR1 | c.109del p.H37Tfs*71 | Frame Shift Del (DEL) | VAF 46/168 reads (27%) | catalogued as rs1264440278; called by pindel, varscan2
- PKP1 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 240/539 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551980188; called by muse, mutect2, varscan2
- PLA1A | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs756340208; called by muse, mutect2, varscan2
- PLEKHA6 | c.1710G>T p.Q570H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1427331410; called by muse, mutect2, varscan2
- PLEKHA6 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1225295333, COSV55332524; called by muse, mutect2, varscan2
- PLEKHG1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376799701; called by muse, mutect2, varscan2
- PLEKHH1 | c.2479C>T p.H827Y | Missense Mutation (SNP) | VAF 120/283 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs1285836146; called by muse, mutect2, varscan2
- PLEKHH3 | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53188798; called by muse, mutect2, varscan2
- PLEKHM1 | c.223A>G p.R75G | Missense Mutation (SNP) | VAF 346/821 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1435313701, COSV69598924; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 94/248 reads (38%) | catalogued as rs772701630; called by mutect2, varscan2
- PLXNA1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.999); catalogued as rs1318681898, COSV52530778; called by muse, mutect2, varscan2
- PLXNB2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 142/371 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV63780090, COSV63780141; called by muse, mutect2, varscan2
- PLXND1 | c.4862G>T p.R1621L | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); catalogued as COSV60720054; called by muse, mutect2, varscan2
- POLD1 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1060501818, COSV54530392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121C | c.2707G>A p.A903T (on ENST00000607367; = p.A661T on NM_001099415.3) | Missense Mutation (SNP) | VAF 125/519 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782333810; called by muse, mutect2, varscan2
- POMT1 | c.1746G>A p.W582* | Nonsense Mutation (SNP) | VAF 311/688 reads (45%) | catalogued as CM061921; called by muse, mutect2, varscan2
- POP1 | c.2575G>A p.V859I | Missense Mutation (SNP) | VAF 239/546 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs1381768312; called by muse, mutect2, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 43/102 reads (42%) | catalogued as rs775721804; called by mutect2, varscan2
- POU3F3 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV100796846; called by muse, mutect2
- PPP2R2B | c.1289C>T p.A430V (on ENST00000394409; = p.A496V on NM_181674.2) | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749797640, COSV60763891; called by muse, mutect2, varscan2
- PRCC | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 132/242 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as rs1388083996; called by muse, mutect2, varscan2
- PRKAG2 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 148/402 reads (37%) | catalogued as COSV55226537; called by muse, mutect2, varscan2
- PRKDC | c.7005C>T p.N2335= | Splice Region (SNP) | VAF 36/80 reads (45%) | catalogued as rs764055873; called by muse, mutect2
- PRR12 | c.1042C>T p.R348W (on ENST00000615927; = p.R1169W on NM_020719.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435355373; called by muse, mutect2, varscan2
- PRR5L | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 95/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773808726; called by muse, mutect2, varscan2
- PRX | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 342/808 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV52533476; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as COSV101122574; called by mutect2, varscan2
- PSPN | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs761645033; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 57/135 reads (42%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PYGM | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs774650561; called by muse, mutect2, varscan2
- RAB11FIP3 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs748822573; called by muse, mutect2, varscan2
- RALGAPA1 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 56/144 reads (39%) | catalogued as COSV51898796; called by muse, mutect2, varscan2
- RALGAPA2 | c.5569G>A p.A1857T | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs772808710, COSV52494152; called by muse, mutect2, varscan2
- RAP1GAP | c.1878A>G p.P626= | Splice Region (SNP) | VAF 60/135 reads (44%) | catalogued as rs750834547; called by muse, mutect2, varscan2
- RASGRF1 | c.2826G>T p.K942N | Missense Mutation (SNP) | VAF 114/281 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV67249525, COSV67250227; called by muse, mutect2, varscan2
- RBL2 | c.510dup p.Q171Sfs*5 | Frame Shift Ins (INS) | VAF 79/251 reads (31%) | catalogued as rs1290780149; called by mutect2, pindel, varscan2
- RBM12 | c.1350del p.F450Lfs*13 | Frame Shift Del (DEL) | VAF 88/226 reads (39%) | catalogued as COSV58290226; called by mutect2, pindel, varscan2
- RCHY1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as rs758856687, COSV61008713; called by muse, mutect2, varscan2
- REEP2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 49/134 reads (37%) | catalogued as rs752698231, COSV54735267; called by muse, mutect2, varscan2
- REG1B | c.370T>C p.W124R | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100521559; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 40/76 reads (53%) | catalogued as rs753959887; called by mutect2, varscan2
- RFX6 | c.1506del p.F502Lfs*5 | Frame Shift Del (DEL) | VAF 106/294 reads (36%) | catalogued as rs1176756248; called by mutect2, varscan2
- RIMBP2 | c.1774del p.H592Tfs*11 | Frame Shift Del (DEL) | VAF 51/142 reads (36%) | catalogued as rs759334405; called by mutect2, pindel, varscan2
- RIPPLY3 | c.514dup p.E172Gfs*69 | Frame Shift Ins (INS) | VAF 71/276 reads (26%) | catalogued as rs1227193558; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 121/293 reads (41%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs752898741; called by mutect2, varscan2
- RREB1 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs115829227, COSV58559813; called by muse, mutect2, varscan2
- RWDD4 | c.204del p.F68Lfs*9 | Frame Shift Del (DEL) | VAF 59/169 reads (35%) | catalogued as rs1325913157; called by mutect2, pindel, varscan2
- SAMD9L | c.4224dup p.Q1409Tfs*49 | Frame Shift Ins (INS) | VAF 54/131 reads (41%) | catalogued as rs759143613; called by mutect2, varscan2
- SAMSN1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368727307; called by muse, mutect2, varscan2
- SCARF2 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 107/217 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs141244105; called by muse, mutect2, varscan2
- SCN8A | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100633779; called by muse, mutect2, varscan2
- SEMA3E | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 143/398 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs777600869, COSV57098928; called by muse, mutect2, varscan2
- SEMA5A | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); catalogued as COSV66802117; called by muse, mutect2, varscan2
- SEMA5B | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 137/309 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs975870235; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as rs750651342; called by mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs764980440, COSV58616367; called by mutect2, varscan2
- SERPINA11 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 188/483 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.401); catalogued as rs200680940; called by muse, mutect2, varscan2
- SERPINA6 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs200104515, COSV100448559; called by muse, mutect2, varscan2
- SERPINA6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as rs202078426, COSV58583804; called by muse, mutect2, varscan2
- SERPINA6 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs750000108; called by muse, mutect2, varscan2
- SERPINI2 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.484); catalogued as rs754540225; called by muse, varscan2
- SETD2 | c.3266G>A p.R1089Q | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs536163785, COSV57437653; called by muse, mutect2, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 63/142 reads (44%) | catalogued as rs759211171; called by mutect2, varscan2
- SGF29 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs774745658, COSV57683089; called by muse, mutect2, varscan2
- SH3BP2 | c.1140dup p.V381Rfs*14 | Frame Shift Ins (INS) | VAF 39/123 reads (32%) | catalogued as rs759199606; called by mutect2, pindel, varscan2
- SHC1 | c.92dup p.E32Gfs*23 | Frame Shift Ins (INS) | VAF 37/110 reads (34%) | catalogued as rs752843778; called by mutect2, varscan2
- SHFL | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1445344591; called by muse, mutect2, varscan2
- SIGLECL1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs369324697, COSV57062874; called by muse, mutect2, varscan2
- SIX6 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 111/225 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166499175; called by muse, mutect2, varscan2
- SLC18A3 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100341111; called by muse, mutect2, varscan2
- SLC22A10 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 164/467 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.305); catalogued as rs1355759817; called by muse, mutect2, varscan2
- SLC26A2 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs760046756; called by muse, mutect2, varscan2
- SLC38A10 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs370058411; called by muse, mutect2, varscan2
- SLC4A5 | c.3267del p.A1091Pfs*17 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | catalogued as rs1558864722; called by mutect2, pindel, varscan2
- SLC5A1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 196/460 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1363968834, COSV56688669; called by muse, mutect2, varscan2
- SLC9B2 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 51/103 reads (50%) | catalogued as COSV100293982; called by muse, mutect2, varscan2
- SLCO6A1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV65808168; called by muse, mutect2, varscan2
- SLX4 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1160715108, COSV53566112; called by muse, mutect2, varscan2
- SMCHD1 | c.2335del p.M779Wfs*12 | Frame Shift Del (DEL) | VAF 49/150 reads (33%) | catalogued as COSV55261052; called by mutect2, pindel, varscan2
- SMPD4 | c.2479_2481del p.F827del (on ENST00000409031 / NM_017951.4; = p.F798del on NM_017751.4) | In Frame Del (DEL) | VAF 161/492 reads (33%) | catalogued as rs761067266; called by pindel, varscan2
- SORBS3 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs149043911; called by muse, mutect2, varscan2
- SOX10 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 148/320 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61005250; called by muse, mutect2, varscan2
- SP2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs373140962; called by muse, mutect2, varscan2
- SPECC1 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs765903879, COSV54954710, COSV54955461; called by muse, mutect2, varscan2
- SPEG | c.1842del p.A615Pfs*105 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | catalogued as rs748658115; called by mutect2, pindel, varscan2
- SPEG | c.6697dup p.Q2233Pfs*90 | Frame Shift Ins (INS) | VAF 154/406 reads (38%) | catalogued as rs752907815; called by mutect2, varscan2
- SPIRE2 | c.1391del p.P464Qfs*53 | Frame Shift Del (DEL) | VAF 73/200 reads (37%) | catalogued as rs1187128946; called by mutect2, pindel, varscan2
- SPTY2D1 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs370983685; called by muse, mutect2, varscan2
- SQSTM1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 305/698 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761822261; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | catalogued as rs748467821; called by mutect2, varscan2
- SRRM2 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs771937307, COSV57068638; called by muse, mutect2, varscan2
- STRIP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 196/408 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747585120; called by muse, mutect2, varscan2
- SUCO | c.1222_1223del p.S408Ffs*5 | Frame Shift Del (DEL) | VAF 51/168 reads (30%) | catalogued as rs1249711260; called by pindel, varscan2
- SULT1C3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs267598831, COSV61253217; called by muse, mutect2, varscan2
- TALDO1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 149/382 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400212400, COSV59798481; called by muse, mutect2, varscan2
- TALDO1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 190/474 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs764703431, COSV59797910; called by muse, mutect2, varscan2
- TAPT1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58823136; called by muse, varscan2
- TAS1R3 | c.1812del p.L606Wfs*43 | Frame Shift Del (DEL) | VAF 120/353 reads (34%) | catalogued as rs777573279, COSV100229689; called by mutect2, pindel, varscan2
- TAS2R14 | c.241del p.M81Cfs*11 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as rs778784911; called by mutect2, pindel, varscan2
- TBC1D12 | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.193); catalogued as rs754511967; called by muse, mutect2, varscan2
- TCHH | c.1750_1752del p.E584del | In Frame Del (DEL) | VAF 108/326 reads (33%) | catalogued as rs750091152; called by pindel, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 72/154 reads (47%) | catalogued as rs763321097; called by mutect2, varscan2
- TEKT1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150562113, COSV100106125; called by muse, mutect2, varscan2
- TELO2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs757625861; called by muse, mutect2, varscan2
- TEX264 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 202/491 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs747830496, COSV58134510; called by muse, mutect2, varscan2
- TFPI | c.536-5del | Splice Region (DEL) | VAF 58/158 reads (37%) | catalogued as rs771312944; called by mutect2, pindel, varscan2
- TG | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 155/395 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as rs751397153, COSV55076042, COSV99600537, COSV99603652; called by muse, mutect2, varscan2
- TGFBR1 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV66626009; called by muse, mutect2, varscan2
- THAP6 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 89/215 reads (41%) | catalogued as rs369772476; called by muse, mutect2, varscan2
- TIAM1 | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 94/262 reads (36%) | catalogued as rs1209725958, COSV99738112; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 138/398 reads (35%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TKTL2 | c.343del p.R115Dfs*12 | Frame Shift Del (DEL) | VAF 46/137 reads (34%) | catalogued as rs542641888, COSV54917504; called by mutect2, pindel, varscan2
- TLR9 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201739665, COSV100645704; called by muse, mutect2, varscan2
- TMEM240 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.174); catalogued as rs945185314; called by muse, mutect2, varscan2
- TMEM259 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as rs773173233; called by muse, mutect2, varscan2
- TMEM86A | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781427046, COSV55009959; called by muse, mutect2, varscan2
- TNFRSF10B | c.1235_1236del p.R412Tfs*7 | Frame Shift Del (DEL) | VAF 44/120 reads (37%) | catalogued as rs1563303865; called by pindel, varscan2
- TNIP1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs200564984; called by muse, mutect2, varscan2
- TNK2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 181/406 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867699975; called by muse, mutect2, varscan2
- TNKS | c.3481C>T p.R1161W | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781688678, COSV60052144; called by muse, mutect2, varscan2
- TNXB | c.7876C>T p.R2626C (on ENST00000647633; = p.R2379C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466093434, COSV64489080; called by muse, mutect2, varscan2
- TONSL | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.402); catalogued as rs146693421; called by muse, mutect2, varscan2
- TOPAZ1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs758880515, COSV100554483; called by muse, mutect2, varscan2
- TPO | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 227/507 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as rs774820583, COSV61097423; called by muse, mutect2, varscan2
- TRIM26 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 131/314 reads (42%) | catalogued as rs765111699, COSV68962835; called by muse, mutect2, varscan2
- TRIM29 | c.1172del p.P391Hfs*19 | Frame Shift Del (DEL) | VAF 62/174 reads (36%) | catalogued as COSV100531750; called by mutect2, varscan2
- TRIM39 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 195/457 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs770499903; called by muse, mutect2, varscan2
- TRIM66 | c.2002del p.Q668Rfs*7 | Frame Shift Del (DEL) | VAF 50/161 reads (31%) | catalogued as rs1186841665; called by mutect2, pindel, varscan2
- TRPM4 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs773399498, COSV53267617; called by muse, mutect2, varscan2
- TRPM6 | c.3331G>A p.V1111M | Missense Mutation (SNP) | VAF 145/312 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs762749956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV5 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 159/363 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758826708, COSV54684214, COSV54688980; called by muse, mutect2, varscan2
- TRPV6 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769173936; called by muse, mutect2, varscan2
- TRRAP | c.11123C>T p.A3708V (on ENST00000359863 / NM_001244580.1; = p.A3679V on NM_003496.3) | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1197135680; called by muse, mutect2, varscan2
- TSGA10IP | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 91/180 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs548379525, COSV56713306; called by muse, mutect2, varscan2
- TSPYL5 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as COSV59071318; called by muse, mutect2, varscan2
- TSSC4 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs560666807; called by muse, mutect2, varscan2
- TTC21B | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 130/307 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs767963660; called by muse, mutect2, varscan2
- TTC28 | c.7370G>A p.R2457H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.77); catalogued as rs751835311; called by muse, mutect2, varscan2
- TTN | c.34598C>A p.P11533H (on ENST00000591111; = p.P10606H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/399 reads (41%) | PolyPhen possibly damaging (0.521); catalogued as rs754527161; called by mutect2, varscan2
- TULP4 | c.1207del p.R403Afs*24 | Frame Shift Del (DEL) | VAF 126/304 reads (41%) | catalogued as rs746002490; called by mutect2, varscan2
- TUSC1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 137/266 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1419865245; called by muse, varscan2
- TUT7 | c.2842del p.Y948Mfs*16 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs751076382; called by mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | catalogued as rs760251146; called by mutect2, varscan2
- UGT3A1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as rs894742328; called by muse, mutect2, varscan2
- UMODL1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs372433102, COSV68555336, COSV68556295, COSV68557200; called by muse, mutect2, varscan2
- UNC80 | c.3206G>A p.R1069Q | Missense Mutation (SNP) | VAF 149/376 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1253303904, COSV99779865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNKL | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1020889263; called by muse, mutect2, varscan2
- USP37 | c.1185del p.D396Ifs*38 | Frame Shift Del (DEL) | VAF 61/173 reads (35%) | catalogued as rs1559187194, COSV51442695; called by mutect2, pindel, varscan2
- USP40 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.732); catalogued as rs548513246, COSV99295549; called by muse, mutect2, varscan2
- USP6 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 259/574 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs764268758, COSV51497206; called by muse, mutect2, varscan2
- UTRN | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761620103, COSV62331139; called by muse, mutect2, varscan2
- UTRN | c.10202C>T p.P3401L | Missense Mutation (SNP) | VAF 167/412 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs565108957; called by muse, mutect2, varscan2
- VDAC1 | c.332del p.N111Mfs*34 | Frame Shift Del (DEL) | VAF 106/218 reads (49%) | catalogued as rs772852563; called by mutect2, varscan2
- VGF | c.1483dup p.R495Pfs*190 | Frame Shift Ins (INS) | VAF 28/81 reads (35%) | catalogued as rs779099185; called by mutect2, varscan2
- VPS9D1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs1422506467; called by muse, mutect2, varscan2
- VWF | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 197/439 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140044866; called by muse, mutect2, varscan2
- WASL | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as rs1012963373; called by muse, mutect2, varscan2
- WDR97 | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.071); catalogued as rs561414111, COSV100075519; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 102/281 reads (36%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XIRP2 | c.4036G>A p.D1346N (on ENST00000628543; = p.D1521N on NM_152381.6) | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54699283; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 69/156 reads (44%) | catalogued as rs1403895317; called by mutect2, pindel, varscan2
- ZAN | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs191610206; called by muse, varscan2
- ZAN | c.4936G>A p.V1646I | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs1196216790; called by muse, mutect2, varscan2
- ZBED1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs142634106, COSV58139814; called by muse, mutect2, varscan2
- ZBTB7A | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775646544, COSV59327332; called by muse, mutect2, varscan2
- ZEB2 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as rs370504406; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 81/230 reads (35%) | catalogued as rs762108866; called by mutect2, pindel, varscan2
- ZFHX4 | c.6310G>A p.A2104T | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs748293539, COSV51479738; called by muse, mutect2, varscan2
- ZFHX4 | c.8249C>A p.S2750Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50829290; called by muse, mutect2, varscan2
- ZFP14 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as rs748284740, COSV54201219; called by muse, mutect2, varscan2
- ZFP64 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 144/343 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs778082549; called by muse, mutect2, varscan2
- ZFR | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1294555150, COSV99415128; called by muse, mutect2, varscan2
- ZNF133 | c.195del p.K65Nfs*122 (on ENST00000316358 / NM_001352454.2; = p.K65Nfs*121 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 57/160 reads (36%) | catalogued as rs753775995, COSV60366352; called by mutect2, varscan2
- ZNF324 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs1428682646, COSV52182414; called by muse, mutect2, varscan2
- ZNF514 | c.1195del p.T399Pfs*21 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs755697811; called by mutect2, varscan2
- ZNF544 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 67/141 reads (48%) | catalogued as rs752467472; called by muse, mutect2, varscan2
- ZNF579 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 149/317 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as rs1196927112; called by muse, mutect2, varscan2
- ZNF607 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 72/146 reads (49%) | catalogued as rs749661817, COSV62205618; called by muse, mutect2, varscan2
- ZNF648 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs754881990, COSV60569527; called by muse, mutect2, varscan2
- ZNF730 | c.580dup p.I194Nfs*11 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | catalogued as rs1568318964; called by mutect2, varscan2
- ZNF746 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 196/471 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202086331, COSV61406352; called by muse, mutect2, varscan2
- ZNF814 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs913158275; called by muse, mutect2, varscan2
- ZNF880 | c.1611del p.K537Nfs*60 | Frame Shift Del (DEL) | VAF 49/220 reads (22%) | catalogued as rs759348115; called by mutect2, pindel, varscan2
- ABAT | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 328/767 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA1 | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ABCB4 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 155/387 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ABCE1 | c.1069del p.M357Wfs*6 | Frame Shift Del (DEL) | VAF 79/192 reads (41%) | called by mutect2, pindel, varscan2
- ABTB1 | c.753del p.E252Sfs*102 (on ENST00000232744 / NM_172027.3; = p.E110Sfs*102 on NM_032548.3) | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- AC109583.1 | c.1027T>C p.Y343H | Missense Mutation (SNP) | VAF 218/461 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACBD5 | c.1539_1540dup p.W514Yfs*21 (on ENST00000375888 / NM_001352568.1; = p.W505Yfs*21 on NM_145698.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 123/377 reads (33%) | called by mutect2, pindel, varscan2
- ADCK2 | c.965A>G p.H322R | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY9 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AFF1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 184/432 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- AGO1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.214); called by muse, mutect2
- AHCTF1 | c.5685del p.E1896Kfs*19 (on ENST00000366508; = p.E1870Kfs*19 on NM_015446.5) | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.12355C>A p.L4119M | Missense Mutation (SNP) | VAF 386/869 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- AIP | c.343del p.L115Wfs*41 | Frame Shift Del (DEL) | VAF 86/243 reads (35%) | called by mutect2, pindel, varscan2
- AKAP13 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD20A1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 137/520 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30B | c.3351G>T p.K1117N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ANKS6 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKUB1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- ANO6 | c.2613del p.K871Nfs*3 | Frame Shift Del (DEL) | VAF 152/460 reads (33%) | called by mutect2, pindel, varscan2
- APBA3 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- APLNR | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- APP | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 171/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AQP1 | c.508del p.A171Pfs*6 | Frame Shift Del (DEL) | VAF 128/329 reads (39%) | called by mutect2, pindel, varscan2
- ARFIP1 | c.513dup p.Y172Ifs*2 (on ENST00000353617 / NM_001287432.1; = p.Y140Ifs*2 on NM_014447.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 58/170 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ARHGAP35 | c.2330del p.L777Wfs*12 | Frame Shift Del (DEL) | VAF 55/151 reads (36%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.544del p.Q182Sfs*52 | Frame Shift Del (DEL) | VAF 88/325 reads (27%) | called by mutect2, varscan2
- ARHGEF39 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 114/292 reads (39%) | called by mutect2, pindel, varscan2
- ARMC3 | c.1934del p.N645Ifs*13 | Frame Shift Del (DEL) | VAF 35/95 reads (37%) | called by mutect2, pindel, varscan2
- ASB6 | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASIC3 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ATN1 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATP10D | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 121/453 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ATP11B | c.2650dup p.Y884Lfs*2 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | called by mutect2, varscan2
- ATP2A1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ATR | c.3385G>A p.G1129S | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- ATRX | c.709_711del p.N237del | In Frame Del (DEL) | VAF 81/160 reads (51%) | called by mutect2, pindel, varscan2
- ATXN1 | c.719del p.P240Hfs*37 | Frame Shift Del (DEL) | VAF 158/413 reads (38%) | called by mutect2, pindel, varscan2
- AVPR1B | c.442del p.Q148Sfs*30 | Frame Shift Del (DEL) | VAF 102/264 reads (39%) | called by mutect2, pindel, varscan2
- BBOX1 | c.720dup p.L241Tfs*5 | Frame Shift Ins (INS) | VAF 70/197 reads (36%) | called by mutect2, pindel, varscan2
- BBS12 | c.1680dup p.E561Rfs*11 | Frame Shift Ins (INS) | VAF 52/174 reads (30%) | called by mutect2, pindel, varscan2
- BCKDK | c.865C>A p.L289I | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- BCL11B | c.2020G>A p.A674T (on ENST00000357195 / NM_001282237.2; = p.A603T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- BCO2 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- BHLHA15 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 238/514 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- BIRC3 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- BTAF1 | c.3437del p.L1146Wfs*27 | Frame Shift Del (DEL) | VAF 100/329 reads (30%) | called by mutect2, pindel, varscan2
- C18orf54 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2
- C19orf44 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 146/380 reads (38%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | called by mutect2, pindel, varscan2
- CA12 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 224/504 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1H | c.6610G>A p.A2204T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACTIN | c.1757A>G p.Q586R | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CAMKK2 | c.1649del p.G550Efs*7 | Frame Shift Del (DEL) | VAF 97/262 reads (37%) | called by mutect2, pindel, varscan2
- CAPRIN2 | c.1024del p.T342Hfs*15 | Frame Shift Del (DEL) | VAF 55/140 reads (39%) | called by mutect2, pindel, varscan2
- CC2D2A | c.4286del p.N1429Mfs*5 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | called by mutect2, pindel, varscan2
- CCDC127 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- CCDC138 | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC150 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CCDC183 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCNI2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 143/341 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CDC7 | c.974del p.K325Rfs*9 | Frame Shift Del (DEL) | VAF 41/106 reads (39%) | called by mutect2, pindel, varscan2
- CEP63 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CFAP20DC | c.878del p.N293Ifs*10 (on ENST00000482387 / NM_001351530.2; = p.N168Ifs*10 on NM_198463.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/156 reads (35%) | called by mutect2, pindel, varscan2
- CFAP44 | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 56/157 reads (36%) | called by mutect2, pindel, varscan2
- CHML | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHRM3 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CHST8 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLCN6 | c.1288del p.C430Vfs*73 | Frame Shift Del (DEL) | VAF 88/247 reads (36%) | called by mutect2, pindel, varscan2
- CNTN5 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL27A1 | c.5368G>A p.A1790T | Missense Mutation (SNP) | VAF 214/523 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREB3L4 | c.328_330del p.P110del | In Frame Del (DEL) | VAF 117/300 reads (39%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.5440-3del | Splice Region (DEL) | VAF 46/129 reads (36%) | called by mutect2, pindel, varscan2
- CT45A1 | c.19_21del p.K7del | In Frame Del (DEL) | VAF 64/498 reads (13%) | called by mutect2, varscan2
- CUBN | c.876T>A p.C292* | Nonsense Mutation (SNP) | VAF 257/617 reads (42%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2
- DCAF12L2 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DCAF8L1 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- DCBLD1 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 210/466 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DDB2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- DDX23 | c.2212A>G p.N738D | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX59 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, varscan2
- DICER1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.119); called by muse, varscan2
- DIDO1 | c.4650del p.A1551Pfs*313 | Frame Shift Del (DEL) | VAF 70/196 reads (36%) | called by mutect2, pindel, varscan2
- DISP1 | c.3969G>T p.E1323D | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLGAP5 | c.1148dup p.L383Ffs*9 | Frame Shift Ins (INS) | VAF 63/152 reads (41%) | called by mutect2, pindel, varscan2
- DMD | c.2662G>C p.E888Q | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH6 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DNAI3 | c.755del p.N252Mfs*34 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- DOCK5 | c.4266dup p.K1423Qfs*22 | Frame Shift Ins (INS) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- DSG1 | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 117/259 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- DUSP18 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2
- DYNC2H1 | c.2031del p.K677Nfs*16 | Frame Shift Del (DEL) | VAF 52/289 reads (18%) | called by mutect2, pindel, varscan2
- DYNC2I1 | c.1241del p.K414Rfs*22 | Frame Shift Del (DEL) | VAF 84/230 reads (37%) | called by mutect2, varscan2
- EBP | c.339-2A>G p.X113_splice | Splice Site (SNP) | VAF 219/495 reads (44%) | called by muse, mutect2, varscan2
- EEF1A2 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 140/310 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- EFTUD2 | c.2723C>A p.P908H | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGLN2 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGR1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 230/530 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EGR3 | c.344del p.P115Rfs*76 | Frame Shift Del (DEL) | VAF 140/352 reads (40%) | called by mutect2, pindel, varscan2
- EHMT1 | c.1792-3del | Splice Region (DEL) | VAF 120/305 reads (39%) | called by mutect2, pindel, varscan2
- EIF2B5 | c.1640A>C p.D547A (on ENST00000647909; = p.D539A on NM_003907.3) | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- EIF4E | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 239/518 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EML5 | c.3122del p.K1041Rfs*15 | Frame Shift Del (DEL) | VAF 32/85 reads (38%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 226/258 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EPB41L1 | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 250/564 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPB41L3 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- EPN3 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 155/449 reads (35%) | called by muse, mutect2, varscan2
- ESPL1 | c.4859T>A p.V1620D | Missense Mutation (SNP) | VAF 224/513 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ETAA1 | c.1653del p.F551Lfs*6 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- ETAA1 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVC | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 247/578 reads (43%) | called by muse, mutect2, varscan2
- F9 | c.1044dup p.G349Wfs*25 | Frame Shift Ins (INS) | VAF 52/125 reads (42%) | called by mutect2, pindel, varscan2
- FAM178B | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM214A | c.469del p.S157Lfs*3 | Frame Shift Del (DEL) | VAF 95/290 reads (33%) | called by pindel, varscan2
- FANCM | c.2589del p.D864Ifs*12 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- FAT1 | c.12659A>G p.H4220R | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBN3 | c.3350G>A p.C1117Y | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCGBP | c.4819C>T p.Q1607* | Nonsense Mutation (SNP) | VAF 137/698 reads (20%) | called by muse, mutect2
- FGF13 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel
- FIGN | c.799del p.A267Hfs*34 | Frame Shift Del (DEL) | VAF 132/383 reads (34%) | called by mutect2, pindel, varscan2
- FILIP1 | c.1555dup p.I519Nfs*13 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- FKBP10 | c.1688_1689del p.T563Sfs*10 | Frame Shift Del (DEL) | VAF 153/468 reads (33%) | called by pindel, varscan2
- FKRP | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FLG | c.6566C>T p.A2189V | Missense Mutation (SNP) | VAF 157/383 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FLII | c.3467A>G p.D1156G | Missense Mutation (SNP) | VAF 204/516 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- FLNA | c.3440G>A p.G1147D | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2
- FLNC | c.7348del p.A2450Lfs*79 | Frame Shift Del (DEL) | VAF 157/466 reads (34%) | called by mutect2, pindel, varscan2
- FN1 | c.4129C>T p.H1377Y | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FNDC3A | c.2207G>A p.R736H (on ENST00000492622 / NM_001079673.2; = p.R680H on NM_014923.5) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FOXE1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FOXF2 | c.1104C>G p.H368Q | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FOXO3B | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious, low confidence (0.01); called by muse, varscan2
- FSHR | c.1328A>C p.D443A | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- GAREM2 | c.1514dup p.V506Gfs*62 | Frame Shift Ins (INS) | VAF 32/125 reads (26%) | called by mutect2, pindel, varscan2
- GDPGP1 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 173/449 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.086); called by muse, mutect2
- GEMIN4 | c.1275del p.F425Lfs*14 | Frame Shift Del (DEL) | VAF 139/331 reads (42%) | called by mutect2, pindel, varscan2
- GFRA2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 177/515 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLIPR1L2 | c.972del p.E325Kfs*38 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- GLP2R | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GPAA1 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GPATCH1 | c.1597C>A p.R533S | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPATCH8 | c.2099C>A p.S700Y | Missense Mutation (SNP) | VAF 188/400 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR149 | c.1174del p.I392Sfs*21 | Frame Shift Del (DEL) | VAF 38/84 reads (45%) | called by mutect2, varscan2
- GPR18 | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.079); called by muse, mutect2
- GPR32 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- GRM2 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GRM7 | c.1885A>G p.S629G | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HCLS1 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCST | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 138/294 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC4 | c.2576A>G p.Y859C | Missense Mutation (SNP) | VAF 160/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDGFL2 | c.727del p.A243Pfs*28 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- HELZ2 | c.7040C>T p.A2347V (on ENST00000467148 / NM_001037335.2; = p.A1778V on NM_033405.3) | Missense Mutation (SNP) | VAF 111/276 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HHIP | c.989del p.N330Ifs*7 | Frame Shift Del (DEL) | VAF 107/302 reads (35%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.6722T>C p.V2241A | Missense Mutation (SNP) | VAF 187/382 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HNRNPUL1 | c.2018del p.G673Vfs*242 | Frame Shift Del (DEL) | VAF 64/214 reads (30%) | called by mutect2, pindel, varscan2
- HOXB9 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 174/408 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HRAS | c.537del p.G180Afs*3 | Frame Shift Del (DEL) | VAF 192/515 reads (37%) | called by mutect2, pindel, varscan2
- HRAS | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 174/390 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HSPG2 | c.9238G>A p.G3080S | Missense Mutation (SNP) | VAF 239/498 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IAH1 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ICE1 | c.1839_1841del p.D614del | In Frame Del (DEL) | VAF 36/100 reads (36%) | called by pindel, varscan2
- IGFN1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG4 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 249/952 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL1R2 | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IL7R | c.799del p.R267Gfs*28 | Frame Shift Del (DEL) | VAF 204/512 reads (40%) | called by mutect2, varscan2
- ILDR2 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- INHBB | c.1109_1111del p.S370del | In Frame Del (DEL) | VAF 108/320 reads (34%) | called by mutect2, pindel, varscan2
- INPP5D | c.1093_1095del p.K365del (on ENST00000445964 / NM_001017915.3; = p.K364del on NM_005541.5) | In Frame Del (DEL) | VAF 16/47 reads (34%) | called by pindel, varscan2*
- INPP5K | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPPL1 | c.3149del p.P1050Lfs*81 | Frame Shift Del (DEL) | VAF 77/213 reads (36%) | called by mutect2, pindel, varscan2
- IRAK2 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 125/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRF2BP2 | c.619_632del p.G207Lfs*42 | Frame Shift Del (DEL) | VAF 78/195 reads (40%) | called by mutect2, pindel, varscan2
- ITGA2B | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 85/960 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2
- ITGA9 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, varscan2
- ITGAD | c.2230dup p.Q744Pfs*32 | Frame Shift Ins (INS) | VAF 67/260 reads (26%) | called by mutect2, pindel, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 34/76 reads (45%) | called by mutect2, varscan2
- ITGB1BP2 | c.9_13del p.L4Sfs*2 | Frame Shift Del (DEL) | VAF 125/257 reads (49%) | called by mutect2, pindel, varscan2
- ITSN2 | c.3578G>A p.W1193* | Nonsense Mutation (SNP) | VAF 89/207 reads (43%) | called by muse, mutect2, varscan2
- JAK2 | c.1512del p.D505Ifs*6 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- KAT6B | c.4070A>T p.E1357V | Missense Mutation (SNP) | VAF 181/445 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KBTBD12 | c.533del p.L178* | Frame Shift Del (DEL) | VAF 43/126 reads (34%) | called by mutect2, pindel, varscan2
- KCNAB2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH2 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 170/439 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KCNJ9 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.315); called by muse, mutect2
- KCNQ5 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- KCNT2 | c.1259T>C p.L420S | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KIAA1549L | c.5293G>C p.A1765P (on ENST00000321505; = p.A2062P on NM_012194.3) | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF26B | c.5503del p.A1835Pfs*41 | Frame Shift Del (DEL) | VAF 78/168 reads (46%) | called by mutect2, varscan2
- KIF3C | c.996del p.N333Mfs*7 | Frame Shift Del (DEL) | VAF 125/329 reads (38%) | called by mutect2, pindel, varscan2
- KIF4A | c.222del p.G75Vfs*44 | Frame Shift Del (DEL) | VAF 63/188 reads (34%) | called by mutect2, pindel, varscan2
- KIF4B | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 157/403 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KLK15 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KLRC1 | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- KMT2B | c.6079_6081del p.E2027del | In Frame Del (DEL) | VAF 63/160 reads (39%) | called by pindel, varscan2
- KNOP1 | c.615dup p.R206Qfs*35 | Frame Shift Ins (INS) | VAF 117/345 reads (34%) | called by mutect2, pindel, varscan2
- KRT83 | c.108del p.Y37Tfs*64 | Frame Shift Del (DEL) | VAF 301/750 reads (40%) | called by mutect2, pindel, varscan2
- LAMA5 | c.1418-2A>G p.X473_splice | Splice Site (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- LAMB2 | c.3561C>G p.C1187W | Missense Mutation (SNP) | VAF 169/426 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARGE2 | c.1177C>A p.L393M | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LAS1L | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
- LBX2 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 191/443 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCOR | c.4254A>C p.K1418N | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- LGALS3BP | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- LILRA2 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 195/470 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LPL | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRCOL1 | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 111/246 reads (45%) | called by muse, mutect2, varscan2
- LRRC8A | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 231/497 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYST | c.8878A>T p.R2960* | Nonsense Mutation (SNP) | VAF 181/430 reads (42%) | called by mutect2, varscan2
- MACF1 | c.18091G>T p.G6031C (on ENST00000372915; = p.G4076C on NM_012090.5) | Missense Mutation (SNP) | VAF 74/178 reads (42%) | called by muse, mutect2, varscan2
- MAP3K1 | c.4345T>C p.W1449R | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM6 | c.2311del p.R771Efs*3 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- METTL4 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MIA | c.372C>T p.D124= | Splice Region (SNP) | VAF 101/225 reads (45%) | called by muse, mutect2, varscan2
- MLPH | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 284/630 reads (45%) | called by muse, mutect2, varscan2
- MORC4 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MOS | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 275/603 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MRC1 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 159/370 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRPS5 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 215/502 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSH5 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 153/344 reads (44%) | called by muse, mutect2, varscan2
- MTERF2 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MTOR | c.4469G>T p.W1490L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MUC12 | c.14579C>A p.S4860Y (on ENST00000379442; = p.S4717Y on NM_001164462.1) | Missense Mutation (SNP) | VAF 232/462 reads (50%) | SIFT tolerated, low confidence (0.17); called by muse, mutect2, varscan2
- MUC5B | c.1100del p.P367Qfs*105 | Frame Shift Del (DEL) | VAF 49/133 reads (37%) | called by mutect2, pindel, varscan2
- MYH11 | c.5425A>G p.K1809E | Missense Mutation (SNP) | VAF 300/655 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MYL2 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 256/591 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, varscan2
- MYO7B | c.784dup p.V262Gfs*4 | Frame Shift Ins (INS) | VAF 41/124 reads (33%) | called by mutect2, pindel, varscan2
- MYOCD | c.684del p.S229Afs*4 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- NADK | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 136/314 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDC1 | c.995T>C p.L332S | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NDUFAF5 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, varscan2
- NDUFB9 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 197/384 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NELL2 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- NMNAT1 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOP2 | c.1241C>T p.A414V (on ENST00000322166 / NM_001258308.2; = p.A410V on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NPIPA1 | c.292+1G>A p.X98_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | called by mutect2, varscan2
- NUP155 | c.1282_1284del p.N428del (on ENST00000231498 / NM_153485.3; = p.N369del on NM_004298.4) | In Frame Del (DEL) | VAF 61/149 reads (41%) | called by mutect2, pindel, varscan2
- NYNRIN | c.4913T>C p.V1638A | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ODF3B | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ODF3B | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
530 further variants in this file (147 protein-altering or splice-affecting, 214 silent, 169 other) are not listed here.
